Somatic mutation profile of tumor specimen TCGA-44-7660-01A (aliquot TCGA-44-7660-01A-11D-2063-08) from TCGA case TCGA-44-7660, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.8 years (26,594 days).
Specimen TCGA-44-7660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15efa039-1f99-4271-b297-4e1f789f14ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7660-10A (Blood Derived Normal), aliquot TCGA-44-7660-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54549144-9502-409c-bb87-d8eedff5c343

The open-access MAF lists 373 somatic variants for this specimen: 278 protein-altering or splice-affecting, 90 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 238, Silent 90, Nonsense Mutation 15, Frame Shift Del 11, Splice Site 5, Splice Region 4, Nonstop Mutation 4, Intron 2, 5'UTR 1, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POMGNT1 | c.354+1G>A p.X118_splice | Splice Site (SNP) | VAF 26/306 reads (8%) | catalogued as rs1057517449, COSV64340071; ClinVar: likely pathogenic; called by muse, mutect2
- RB1 | c.1814+2T>A p.X605_splice | Splice Site (SNP) | VAF 46/78 reads (59%) | hotspot (GDC flag); catalogued as CS011547, COSV57310724, COSV57329041; called by muse, mutect2, varscan2
- A2ML1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV55291994; called by muse, mutect2, varscan2
- ABCA5 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67017214; called by muse, mutect2, varscan2
- ABRA | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV61732605; called by muse, mutect2
- AC008676.3 | c.623T>C p.L208S | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV56636995; called by muse, mutect2, varscan2
- ACTN1 | c.2533A>G p.M845V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs766310248, COSV51993051; called by muse, mutect2, varscan2
- ADAM29 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1156510077, COSV63664413; called by muse, mutect2, varscan2
- ADAMTS12 | c.2102G>C p.C701S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258773, COSV61265018; called by muse, mutect2, varscan2
- ADAMTS5 | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53179932; called by muse, mutect2, varscan2
- ADGRB3 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV65399764; called by muse, mutect2, varscan2
- ADGRG7 | c.2064C>A p.Y688* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV56297498, COSV99840593; called by muse, mutect2, varscan2
- AGMO | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV61114366; called by muse, mutect2, varscan2
- AHNAK | c.13622T>C p.V4541A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV57216209; called by muse, mutect2, varscan2
- AIDA | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV60664232; called by muse, mutect2, varscan2
- AKAP13 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV63453830; called by muse, mutect2, varscan2
- AKNAD1 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV62199265; called by muse, mutect2, varscan2
- AL592490.1 | c.1796G>C p.R599P | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101308302, COSV69426613; called by muse, mutect2, varscan2
- ALG6 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54765445; called by muse, mutect2, varscan2
- ANK3 | c.3781A>G p.T1261A (on ENST00000280772 / NM_001320874.2; = p.T395A on NM_001149.3) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55061747; called by muse, mutect2, varscan2
- ANO6 | c.1707A>G p.I569M | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100262943, COSV57662197; called by muse, mutect2, varscan2
- AP3B1 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54885364; called by muse, mutect2, varscan2
- ARHGEF12 | c.3085A>G p.K1029E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63105288; called by muse, mutect2
- ARL13B | c.473G>T p.C158F (on ENST00000394222 / NM_001174150.2; = p.C51F on NM_144996.4) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57398792; called by muse, mutect2, varscan2
- ARMC4 | c.382+1G>A p.X128_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as rs1380463764, COSV53465654; called by muse, varscan2
- ASXL1 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60109536; called by muse, mutect2, varscan2
- ASXL1 | c.4261C>T p.L1421F | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.16); catalogued as COSV60109546; called by muse, mutect2, varscan2
- ATP2B4 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100398031, COSV58178926; called by muse, mutect2, varscan2
- ATP6V1B1 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52269881; called by muse, mutect2, varscan2
- AZIN1 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61480134, COSV61480291; called by muse, mutect2, varscan2
- BRCA2 | c.6728C>G p.S2243C | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs876659031, COSV66455077; ClinVar: uncertain significance; called by muse, mutect2
- BSND | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV64870755; called by muse, mutect2, varscan2
- BTN3A1 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV50024918; called by muse, mutect2, varscan2
- C19orf47 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63509360; called by muse, mutect2, varscan2
- C21orf91 | c.797A>T p.H266L (on ENST00000284881 / NM_001100420.2; = p.H265L on NM_017447.4) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53033045; called by muse, mutect2, varscan2
- CALCR | c.1456C>A p.Q486K (on ENST00000649521 / NM_001164737.2; = p.Q470K on NM_001742.4) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV64008817; called by muse, mutect2, varscan2
- CARD11 | c.2063G>C p.R688P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV62753993, COSV62755582; called by muse, mutect2, varscan2
- CDAN1 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51163414; called by muse, mutect2, varscan2
- CDH22 | c.856A>T p.I286F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV64837935; called by muse, mutect2, varscan2
- CDK12 | c.4099G>A p.V1367I (on ENST00000447079 / NM_016507.4; = p.V1358I on NM_015083.3) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as COSV71000660, COSV71001028; called by muse, mutect2, varscan2
- CDNF | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV65684431; called by muse, mutect2, varscan2
- CEP152 | c.4651A>G p.K1551E (on ENST00000380950 / NM_001194998.2; = p.K1495E on NM_014985.4) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV57860234; called by muse, mutect2, varscan2
- CEP57L1 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.268); catalogued as COSV100425901; called by muse, mutect2, varscan2
- CHAF1A | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56672697, COSV56675807; called by muse, mutect2, varscan2
- CHD9 | c.7852C>G p.L2618V (on ENST00000398510 / NM_001382353.1; = p.L2602V on NM_025134.7) | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54607890, COSV54611433; called by muse, mutect2
- COL11A2 | c.1991G>T p.G664V (on ENST00000341947 / NM_080680.3; = p.G557V on NM_080679.2) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59497884; called by muse, mutect2, varscan2
- COL27A1 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV61927066; called by muse, mutect2, varscan2
- COL4A6 | c.1244C>A p.P415Q | Missense Mutation (SNP) | VAF 79/114 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV57868493; called by muse, mutect2, varscan2
- COL5A2 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.115); catalogued as COSV66410510; called by muse, mutect2, varscan2
- CPAMD8 | c.3776C>T p.T1259I (on ENST00000651564; = p.T1212I on NM_015692.5) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71596718, COSV71597559; called by muse, mutect2, varscan2
- CPE | c.788G>C p.S263T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV68580735; called by muse, mutect2, varscan2
- CRYBG1 | c.5213G>T p.G1738V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64812546; called by muse, mutect2, varscan2
- CSMD2 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.309); catalogued as COSV53919829; called by muse, mutect2, varscan2
- CUBN | c.7723C>G p.P2575A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64717767; called by muse, varscan2
- CUL9 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52729715; called by muse, mutect2, varscan2
- DHX9 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV62360058; called by muse, mutect2, varscan2
- DLGAP2 | c.976T>A p.C326S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.988); catalogued as COSV70099432; called by muse, mutect2
- DNAH7 | c.3886G>C p.G1296R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425033687, COSV56768453; called by muse, mutect2, varscan2
- DOK6 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs893415202, COSV101234285, COSV66932088; called by muse, mutect2
- DPYS | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV60906579, COSV60909549; called by muse, mutect2, varscan2
- EEPD1 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54199205; called by muse, mutect2, varscan2
- EHBP1 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV50421814; called by muse, mutect2
- ENPP2 | c.887C>A p.P296Q | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017749; called by muse, mutect2, varscan2
- EPC2 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs761809638, COSV51541728, COSV51544969; called by muse, mutect2, varscan2
- ETNPPL | c.710A>T p.H237L | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV56596104; called by muse, mutect2, varscan2
- EXOC3L1 | c.1190T>A p.L397Q | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52046771; called by muse, mutect2, varscan2
- FARP1 | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV60339466; called by muse, mutect2, varscan2
- FAT1 | c.1942A>G p.T648A | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV71674603; called by muse, mutect2, varscan2
- FBXO33 | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV53234550; called by muse, mutect2, varscan2
- FCAR | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62029920; called by muse, mutect2, varscan2
- FLG | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 75/506 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs374461110, COSV64242847, COSV64243659; called by muse, mutect2, varscan2
- FMO1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs28360397; called by muse, mutect2, varscan2
- FOLR1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs1417053720, COSV56616302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOS | c.949G>C p.A317P | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV57839694; called by muse, mutect2
- FOXJ3 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV62362803; called by muse, mutect2, varscan2
- FRG2 | c.330A>C p.A110= | Splice Region (SNP) | VAF 43/85 reads (51%) | catalogued as rs1554029970, COSV66460095, COSV99060228; called by muse, mutect2, varscan2
- FRRS1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs890508746, COSV54922562; called by muse, mutect2, varscan2
- FSIP2 | c.20493G>T p.K6831N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58088648; called by muse, mutect2, varscan2
- GABRR1 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65619622; called by muse, mutect2, varscan2
- GALNT11 | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); catalogued as COSV57426403; called by muse, mutect2
- GART | c.1690T>G p.C564G | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63113910; called by muse, mutect2, varscan2
- GCG | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1461309540, COSV64961535; called by muse, mutect2, varscan2
- GGTLC2 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV101312245; called by muse, mutect2, varscan2
- GNAL | c.983T>A p.I328N (on ENST00000269162 / NM_001142339.3; = p.I405N on NM_182978.4) | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52328311; called by muse, mutect2, varscan2
- GPR149 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 41/142 reads (29%) | catalogued as COSV67667759; called by muse, mutect2, varscan2
- GPR156 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779085583, COSV59940493; called by muse, mutect2, varscan2
- GRIK2 | c.2727A>C p.*909Yext*34 | Nonstop Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV59741756; called by muse, mutect2, varscan2
- GRIN2B | c.359T>A p.L120H | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.025); catalogued as COSV74206234; called by muse, mutect2
- HCN1 | c.744C>A p.Y248* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57515478; called by muse, mutect2, varscan2
- HECW1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs746740077, COSV67831339; called by muse, mutect2
- HELZ | c.5162A>C p.Q1721P | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV62378873; called by muse, mutect2, varscan2
- HMGCR | c.2647T>C p.C883R | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV55316095; called by muse, mutect2, varscan2
- HNRNPL | c.1681T>A p.F561I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55493161; called by muse, mutect2, varscan2
- HSP90B1 | c.1745A>G p.E582G | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55355873; called by muse, mutect2
- IFT46 | c.577A>G p.K193E (on ENST00000264021 / NM_001168618.2; = p.K244E on NM_020153.3) | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50594447; called by muse, mutect2, varscan2
- IFT74 | c.1707G>T p.E569D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66287352; called by muse, mutect2, varscan2
- IGSF10 | c.2797G>T p.V933F | Missense Mutation (SNP) | VAF 104/461 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56786443; called by muse, mutect2, varscan2
- IPO11 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs533782408, COSV57577100; called by muse, mutect2, varscan2
- ITGA3 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV50315658; called by muse, mutect2
- ITIH6 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV54489960; called by muse, mutect2, varscan2
- ITLN1 | c.405+1G>A p.X135_splice | Splice Site (SNP) | VAF 10/219 reads (5%) | catalogued as rs1461642195, COSV58275575; called by muse, mutect2
- JADE3 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs1449241636, COSV54467129; called by muse, mutect2, varscan2
- KCNC2 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs746501735, COSV54361296; called by muse, mutect2, varscan2
- KCNC2 | c.1342T>A p.W448R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100129369; called by muse, mutect2, varscan2
- KDM4C | c.1766A>T p.Q589L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV67187451; called by muse, mutect2, varscan2
- KEAP1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIF19 | c.1958A>T p.Q653L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV63429631; called by muse, mutect2, varscan2
- KIF20B | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs1050818241, COSV53306948; called by muse, mutect2, varscan2
- KIRREL2 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52876879, COSV52877148; called by muse, mutect2, varscan2
- KLK4 | c.731C>G p.T244S | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.42); catalogued as COSV60676477; called by muse, mutect2, varscan2
- KPRP | c.1088G>A p.W363* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV64221890; called by muse, mutect2, varscan2
- KRT6A | c.1540A>T p.S514C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as COSV58105610; called by muse, varscan2
- KRT6A | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753948082, COSV58105632; called by muse, mutect2, varscan2
- KRTAP10-9 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 206/435 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59965878; called by muse, mutect2, varscan2
- KRTAP26-1 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.212); catalogued as COSV62128910; called by muse, mutect2, varscan2
- KRTAP5-10 | c.164G>C p.C55S | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.346); catalogued as COSV64794120, COSV64794925; called by muse, mutect2, varscan2
- LAMA4 | c.1298G>C p.R433P (on ENST00000230538 / NM_001105206.3; = p.R426P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57896588, COSV57898555; called by muse, mutect2, varscan2
- LGR6 | c.605C>G p.P202R (on ENST00000367278 / NM_001017403.1; = p.P150R on NM_021636.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55158687; called by muse, mutect2, varscan2
- LIPT1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV60739808; called by muse, mutect2, varscan2
- LRRC7 | c.855G>T p.M285I (on ENST00000651989 / NM_001370785.2; = p.M252I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as COSV99228233; called by muse, mutect2, varscan2
- LRRC7 | c.856G>T p.D286Y (on ENST00000651989 / NM_001370785.2; = p.D253Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV50446575, COSV99228236; called by muse, mutect2, varscan2
- LRRIQ3 | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs886413908, COSV63044839; called by muse, mutect2, varscan2
- LRRIQ3 | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV63044846; called by mutect2, varscan2
- LRRTM1 | c.725G>T p.R242M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV54442744; called by muse, mutect2, varscan2
- LUC7L2 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV54926719; called by muse, mutect2
- LUM | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128381; called by muse, mutect2, varscan2
- LYPD4 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV58027940; called by muse, mutect2, varscan2
- MACF1 | c.3657G>T p.E1219D | Missense Mutation (SNP) | VAF 15/164 reads (9%) | catalogued as COSV58377842; called by muse, mutect2
- MARCHF6 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56882324, COSV56882852; called by muse, mutect2, varscan2
- MATN4 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | PolyPhen probably damaging (0.999); catalogued as COSV59213934; called by muse, mutect2, varscan2
- MCF2L2 | c.1296G>C p.Q432H | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.541); catalogued as COSV61054917; called by muse, mutect2
- MGAT5B | c.1873T>C p.Y625H (on ENST00000569840 / NM_001199172.2; = p.Y623H on NM_144677.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1460745376, COSV56930437; called by muse, mutect2
- MIP | c.39A>G p.I13M | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV57788542; called by muse, mutect2, varscan2
- MLEC | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57329752; called by muse, mutect2, varscan2
- MMP24 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV55770619; called by muse, mutect2, varscan2
- MMRN1 | c.1639T>C p.S547P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.365); catalogued as COSV53335156; called by muse, mutect2, varscan2
- MRC1 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58890024; called by muse, mutect2, varscan2
- MRE11 | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV60577544; called by muse, mutect2, varscan2
- MROH2B | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV68185083; called by muse, mutect2, varscan2
- MUC17 | c.9772G>T p.E3258* | Nonsense Mutation (SNP) | VAF 92/876 reads (11%) | catalogued as COSV60291160; called by muse, mutect2, varscan2
- MYH15 | c.2196A>G p.Q732= | Splice Region (SNP) | VAF 16/138 reads (12%) | catalogued as COSV56311776; called by muse, mutect2, varscan2
- MYH2 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV55439963; called by muse, mutect2, varscan2
- MYH8 | c.2225A>G p.K742R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.173); catalogued as COSV67966406; called by muse, mutect2, varscan2
- MYO1A | c.579A>T p.K193N | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV55654608; called by muse, mutect2, varscan2
- NCKAP5L | c.3653C>T p.P1218L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1471338011, COSV60130207; called by muse, mutect2, varscan2
- NCSTN | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1178436994, COSV54188249; called by muse, mutect2, varscan2
- NDNF | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV65633724; called by muse, mutect2, varscan2
- NDUFS6 | c.374A>T p.*125Lext*44 | Nonstop Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as COSV56876982; called by muse, mutect2, varscan2
- NEB | c.12059T>A p.V4020E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV51423647; called by muse, mutect2, varscan2
- NEB | c.5881C>A p.R1961S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51423686; called by muse, mutect2, varscan2
- NELL1 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV54273514; called by muse, mutect2
- NLRC5 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs199937881, COSV52656808, COSV99346657; called by muse, mutect2, varscan2
- NLRP5 | c.2003G>T p.W668L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66765223; called by muse, mutect2, varscan2
- NLRP6 | c.2180T>G p.L727R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV56460167; called by muse, mutect2
- NNMT | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55474013; called by muse, mutect2, varscan2
- NOL6 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as COSV53042594; called by muse, mutect2, varscan2
- NRAP | c.2889G>T p.Q963H (on ENST00000359988 / NM_001322945.2; = p.Q928H on NM_006175.4) | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100748509; called by muse, mutect2, varscan2
- NRAP | c.2888A>C p.Q963P (on ENST00000359988 / NM_001322945.2; = p.Q928P on NM_006175.4) | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100748510; called by muse, mutect2, varscan2
- NSUN4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV61063288; called by muse, mutect2, varscan2
- NT5C1A | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52494846; called by muse, mutect2, varscan2
- NTM | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66181952; called by muse, mutect2, varscan2
- OR10G8 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 73/247 reads (30%) | catalogued as COSV70908660, COSV70909509; called by muse, varscan2
- OR10J3 | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59954517; called by muse, mutect2
- OR2A25 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV68717294, COSV68717296; called by muse, mutect2, varscan2
- OR2M3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 134/510 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV71759089; called by muse, mutect2, varscan2
- OR2T1 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1201490645, COSV63542139; called by muse, mutect2, varscan2
- OR2T6 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs138116574, COSV63216479; called by muse, mutect2, varscan2
- OR51F1 | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58579994; called by muse, mutect2
- OR51F2 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1372722890, COSV59064969; called by muse, mutect2
- OR5AK2 | c.818T>A p.V273E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58804650; called by muse, mutect2, varscan2
- OR5AR1 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV57254093; called by muse, mutect2, varscan2
- OR5D14 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59455806; called by muse, mutect2, varscan2
- OR5T1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs748886812, COSV57303101; called by muse, mutect2
- OR5T1 | c.937A>T p.I313F | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57303115; called by muse, mutect2
- OR6C68 | c.571T>A p.S191T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV65563392; called by muse, mutect2, varscan2
- OR6K3 | c.834C>A p.S278R (on ENST00000368146; = p.S262R on NM_001005327.2) | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs146136418, COSV63745771; called by muse, mutect2, varscan2
- OR8B12 | c.61G>T p.G21* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV60911922; called by muse, mutect2, varscan2
- OR8H1 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV57294385; called by muse, mutect2, varscan2
- OSBP | c.1825T>G p.C609G | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55663371; called by muse, mutect2, varscan2
- OTULIN | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52505843; called by muse, mutect2, varscan2
- PALB2 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1379618411, COSV55165873; called by muse, mutect2, varscan2
- PARP1 | c.2410G>T p.V804F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV64690837; called by muse, mutect2, varscan2
- PARP4 | c.2030A>G p.K677R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67962419; called by muse, mutect2, varscan2
- PCDH11X | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.816); catalogued as COSV100015924, COSV53441394, COSV53472899; called by muse, mutect2
- PCDH15 | c.4237G>T p.A1413S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV57325781; called by muse, mutect2, varscan2
- PCDHB8 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 42/487 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV50775327; called by muse, mutect2
- PCDHGB2 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV53963675; called by muse, mutect2, varscan2
- PCGF3 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62859684; called by muse, mutect2
- PDZD3 | c.1715A>G p.*572Wext*20 (on ENST00000531114; = p.*492Wext*20 on NM_024791.4) | Nonstop Mutation (SNP) | VAF 61/161 reads (38%) | catalogued as COSV59540283; called by muse, mutect2, varscan2
- PHIP | c.5417G>T p.R1806L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV51505450; called by muse, mutect2, varscan2
- PIK3C2A | c.1661T>C p.L554S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56403638; called by muse, mutect2
- PLCE1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.012); catalogued as COSV53353982; called by muse, mutect2, varscan2
- PLEC | c.7613A>T p.E2538V (on ENST00000322810 / NM_201380.4; = p.E2428V on NM_000445.5) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV59646003; called by muse, mutect2, varscan2
- PLG | c.1892C>G p.S631* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | catalogued as COSV57517084; called by muse, mutect2, varscan2
- PLPP7 | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV64836009; called by muse, mutect2, varscan2
- PPFIA1 | c.2030C>G p.S677* | Nonsense Mutation (SNP) | VAF 33/276 reads (12%) | catalogued as COSV54136001; called by muse, mutect2, varscan2
- PPP6C | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65208123; called by muse, mutect2, varscan2
- PRICKLE2 | c.2104G>C p.D702H (on ENST00000295902; = p.D646H on NM_198859.4) | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55766772; called by muse, mutect2
- PRKAA2 | c.1285del p.E429Nfs*4 | Frame Shift Del (DEL) | VAF 133/252 reads (53%) | catalogued as COSV64805246; called by mutect2, pindel, varscan2
- PTPRF | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV63445708; called by muse, mutect2, varscan2
- QSOX1 | c.1632C>G p.F544L | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62580641; called by muse, mutect2
- RBAK-RBAKDN | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs141093707, COSV67760421; called by muse, mutect2, varscan2
- RBBP6 | c.3979G>T p.E1327* | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as COSV60505742, COSV60509139; called by muse, mutect2, varscan2
- REEP1 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs745678615, COSV51257064; called by muse, mutect2, varscan2
- REV3L | c.1537A>G p.S513G | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV62619749; called by muse, mutect2, varscan2
- RIT2 | c.186G>C p.R62S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.953); catalogued as COSV56301372, COSV99951063; called by muse, mutect2, varscan2
- RLF | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV65652111, COSV65653165; called by muse, mutect2
- RP1L1 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV66756128; called by muse, mutect2, varscan2
- RPA3 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56188604; called by muse, mutect2, varscan2
- RXRG | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63232288; called by muse, varscan2
- RYR2 | c.8254A>C p.K2752Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63663110, COSV63689829; called by muse, mutect2, varscan2
- SAMHD1 | c.1015del p.R339Vfs*5 | Frame Shift Del (DEL) | VAF 88/347 reads (25%) | catalogued as COSV53429086, COSV53431512; called by mutect2, pindel, varscan2
- SCAF8 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63200244; called by muse, mutect2, varscan2
- SCP2 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV65261335; called by muse, mutect2
- SGPP1 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55975626; called by muse, mutect2
- SHOX2 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55830277; called by muse, mutect2
- SIPA1L3 | c.4588G>C p.D1530H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV55916142; called by muse, mutect2, varscan2
- SLC39A8 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63222962; called by muse, mutect2, varscan2
- SLC6A9 | c.998G>A p.R333H (on ENST00000360584 / NM_201649.4; = p.R279H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1169543958, COSV62210952; called by muse, mutect2, varscan2
- SLC7A14 | c.1992G>T p.V664= | Splice Region (SNP) | VAF 47/258 reads (18%) | catalogued as COSV51583419; called by muse, mutect2, varscan2
- SMARCA2 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61808603; called by muse, mutect2, varscan2
- SMARCA5 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as COSV51644894; called by muse, mutect2
- SMCO3 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV53763217; called by muse, mutect2, varscan2
- SOX5 | c.2206T>C p.Y736H | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV58632809; called by muse, mutect2, varscan2
- SPEF2 | c.4278T>G p.N1426K | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV57429689; called by muse, mutect2, varscan2
- SPEN | c.8884G>A p.D2962N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV65363130; called by muse, mutect2, varscan2
- SPHKAP | c.2941A>G p.R981G | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60882239; called by muse, mutect2
- STAG2 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV54360668; called by muse, mutect2, varscan2
- TAF3 | c.1605G>C p.K535N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as COSV60207321; called by muse, mutect2, varscan2
- TBC1D17 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV55579107; called by muse, mutect2
- TBX4 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs145825881; called by muse, mutect2, varscan2
- TDRD6 | c.2978C>G p.T993R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369734344, COSV60176312; called by muse, mutect2, varscan2
- TFAP2D | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50421392; called by muse, mutect2, varscan2
- TLE4 | c.1565G>C p.S522T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV54633302; called by muse, mutect2, varscan2
- TMC6 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59809448, COSV59810167; called by muse, mutect2, varscan2
- TMEM175 | c.379-1G>A p.X127_splice | Splice Site (SNP) | VAF 7/102 reads (7%) | catalogued as COSV53279307; called by muse, mutect2
- TMEM87B | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1011637846, COSV51715696; called by muse, mutect2, varscan2
- TNR | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); catalogued as COSV54890009; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRDN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 37/78 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs779415181, COSV62123436; called by muse, mutect2, varscan2
- TRIM31 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV65059856; called by muse, mutect2
- TRPS1 | c.1711C>A p.L571I (on ENST00000220888 / NM_001330599.2; = p.L584I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV55244270; called by muse, mutect2, varscan2
- TTN | c.61250G>T p.R20417L (on ENST00000591111; = p.R12993L on NM_003319.4) | Missense Mutation (SNP) | VAF 36/82 reads (44%) | PolyPhen benign (0.247); catalogued as rs753077711, COSV60113637; called by muse, mutect2, varscan2
- TTN | c.53353G>T p.D17785Y (on ENST00000591111; = p.D10361Y on NM_003319.4) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | PolyPhen benign (0.444); catalogued as COSV60113693; called by muse, mutect2, varscan2
- TULP2 | c.1069G>T p.V357F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV55478453; called by muse, mutect2, varscan2
- UBR2 | c.2412G>A p.E804= | Splice Region (SNP) | VAF 20/169 reads (12%) | catalogued as COSV65750509; called by muse, mutect2, varscan2
- ULBP1 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1210327490, COSV57664407; called by muse, mutect2, varscan2
- ULBP3 | c.703A>C p.I235L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1323012079, COSV66254283; called by muse, mutect2, varscan2
- UNC13C | c.2473A>C p.S825R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as rs1354085166, COSV52881926; called by muse, mutect2, varscan2
- UNC5B | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV58977771; called by muse, mutect2
- UNC79 | c.4067G>C p.G1356A (on ENST00000393151 / NM_001346218.2; = p.G1179A on NM_020818.5) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV56391650, COSV56392180; called by muse, mutect2
- USP16 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV57625785; called by muse, mutect2, varscan2
- VAMP7 | c.54T>A p.H18Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV52902091; called by muse, mutect2
- VPS13C | c.7778A>T p.Q2593L (on ENST00000644861 / NM_020821.3; = p.Q2550L on NM_017684.5) | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51221013; called by muse, mutect2, varscan2
- WDR72 | c.2107T>C p.S703P | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64748208; called by muse, mutect2
- WFDC2 | c.284A>T p.D95V | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54151598; called by muse, mutect2, varscan2
- XIRP1 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV61137562, COSV61138980; called by muse, mutect2, varscan2
- XIRP2 | c.9567A>G p.I3189M (on ENST00000628543; = p.I3364M on NM_152381.6) | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54706350; called by muse, mutect2, varscan2
- ZFHX4 | c.4806C>A p.Y1602* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV50972855; called by muse, mutect2, varscan2
- ZNF107 | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV100788491, COSV61329253; called by muse, mutect2, varscan2
- ZNF146 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1310700863, COSV61931335, COSV61931842, COSV61931929; called by muse, mutect2, varscan2
- ZNF174 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51902980, COSV51903254; called by muse, mutect2, varscan2
- ZNF239 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs776731163, COSV60018939; called by muse, mutect2, varscan2
- ZNF471 | c.1649A>G p.K550R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57291648; called by muse, mutect2, varscan2
- ZNF536 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.046); catalogued as COSV62825842; called by muse, mutect2, varscan2
- ZNF536 | c.1049G>T p.C350F | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62825848; called by muse, mutect2, varscan2
- ZNF618 | c.1833C>G p.I611M (on ENST00000374126 / NM_001318042.2; = p.I518M on NM_133374.2) | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV55916995, COSV55922783; called by muse, mutect2, varscan2
- ARHGAP30 | c.650del p.G217Vfs*68 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- CPB1 | c.981+1del | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | called by mutect2, pindel, varscan2
- CST9L | c.385del p.R129Gfs*4 | Frame Shift Del (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- CUBN | c.6966del p.T2323Hfs*11 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- HSPA12A | c.1532del p.G511Afs*29 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- LMX1B | c.1204_*5del | Nonstop Mutation (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- OSCP1 | c.850del p.E284Kfs*13 (on ENST00000356637 / NM_001330493.1; = p.E274Kfs*13 on NM_145047.5) | Frame Shift Del (DEL) | VAF 93/576 reads (16%) | called by mutect2, pindel, varscan2
- SAMD15 | c.1694del p.C565Ffs*25 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- SCARB1 | c.1134_1143del p.G379* | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- VWF | c.2730del p.N911Ifs*9 | Frame Shift Del (DEL) | VAF 31/136 reads (23%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.300C>T p.R100= | Silent (SNP) | VAF 116/230 reads (50%) | catalogued as rs781329334, COSV59444252; called by muse, mutect2, varscan2
- ALG10B | c.621G>A p.E207= | Silent (SNP) | VAF 85/276 reads (31%) | catalogued as COSV58143498; called by muse, mutect2, varscan2
- ANXA11 | c.717A>T p.L239= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV55416655; called by muse, mutect2, varscan2
- AP1M1 | c.984G>A p.T328= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as rs780709008, COSV52226914; called by muse, mutect2, varscan2
- ASIC4 | c.297G>A p.V99= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV61732038; called by muse, mutect2, varscan2
- BSN | c.6078C>T p.G2026= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as rs1334961218, COSV56519870; called by muse, mutect2
- C2CD3 | c.5106G>T p.L1702= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as COSV58094054; called by muse, mutect2, varscan2
- CCL7 | c.162C>G p.T54= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV52337140; called by muse, mutect2, varscan2
- CD109 | c.3381A>T p.S1127= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV54650645; called by muse, mutect2, varscan2
- CFAP61 | c.2496C>T p.T832= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as rs1288853820, COSV55632458; called by muse, mutect2, varscan2
- CNTNAP2 | c.120C>A p.V40= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62192253; called by muse, mutect2, varscan2
- COCH | c.466C>A p.R156= (on ENST00000216361 / NM_001347720.1; = p.R91= on NM_004086.3) | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs540895576, COSV53550459, COSV53551309; called by muse, mutect2, varscan2
- CTNND2 | c.391C>T p.L131= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as COSV58894537; called by muse, mutect2, varscan2
- CUBN | c.5277C>T p.P1759= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs375219681, COSV64717772; called by muse, mutect2, varscan2
- CUL9 | c.3180C>T p.F1060= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV52729725; called by muse, mutect2, varscan2
- DLC1 | c.2505T>A p.S835= (on ENST00000276297 / NM_001348081.2; = p.S398= on NM_006094.5) | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as COSV52308229; called by muse, mutect2, varscan2
- DNMBP | c.853C>T p.L285= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV60627066; called by muse, mutect2
- DSC3 | c.471A>G p.Q157= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV64573374; called by muse, mutect2, varscan2
- EPHA10 | c.471G>A p.A157= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as COSV60403918; called by muse, mutect2, varscan2
- EPHB4 | c.1620G>C p.L540= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV62269166; called by muse, mutect2, varscan2
- ERCC6L | c.3162A>C p.S1054= | Silent (SNP) | VAF 51/72 reads (71%) | catalogued as COSV57820948; called by muse, mutect2, varscan2
- FAT3 | c.8355C>T p.A2785= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs759517171, COSV53121285; called by muse, mutect2, varscan2
- FN3KRP | c.267G>A p.E89= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV53929918; called by muse, mutect2, varscan2
- FRMPD1 | c.924C>A p.L308= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV66700665; called by muse, mutect2, varscan2
- GALNT2 | c.408G>T p.P136= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV64195361; called by muse, mutect2, varscan2
- GATA1 | c.699G>A p.K233= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV64962439; called by muse, mutect2, varscan2
- GDI1 | c.978C>G p.V326= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV50131469; called by muse, mutect2, varscan2
- GIMAP4 | c.789C>A p.I263= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV55432913, COSV55434499; called by muse, mutect2
- GPC2 | c.963G>T p.G321= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV52785309; called by muse, mutect2, varscan2
- HECTD1 | c.5484G>T p.T1828= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV67946769; called by muse, mutect2, varscan2
- HMGB4 | c.375G>A p.K125= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV53919820; called by muse, mutect2, varscan2
- IGF2BP2 | c.1437C>T p.T479= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs145090990, COSV60485824; called by muse, mutect2, varscan2
- IGKV2D-24 | c.198C>A p.G66= | Silent (SNP) | VAF 110/238 reads (46%) | catalogued as rs1408761408; called by muse, mutect2, varscan2
- IGKV2D-30 | c.126C>A p.S42= | Silent (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- KANK4 | c.2085A>T p.A695= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV62987231; called by muse, mutect2
- KCND2 | c.618A>G p.T206= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV58567816; called by muse, mutect2
- KMT2D | c.4059G>A p.E1353= | Silent (SNP) | VAF 33/301 reads (11%) | catalogued as rs1409600020, COSV56449533; called by muse, mutect2, varscan2
- LCE1A | c.123T>C p.S41= | Silent (SNP) | VAF 61/197 reads (31%) | catalogued as COSV58727087; called by muse, mutect2, varscan2
- MAGEB6B | c.93T>G p.T31= | Silent (SNP) | VAF 55/84 reads (65%) | called by muse, mutect2, varscan2
- MAGI1 | c.2679G>A p.V893= (on ENST00000402939 / NM_001033057.2; = p.V921= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV58330018; called by muse, mutect2, varscan2
- MARS2 | c.351C>G p.V117= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV56571581; called by muse, mutect2, varscan2
- MBP | c.771A>T p.P257= (on ENST00000355994 / NM_001025101.2; = p.P139= on NM_002385.3) | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV62829511; called by muse, mutect2, varscan2
- MCU | c.732C>G p.A244= | Silent (SNP) | VAF 78/364 reads (21%) | catalogued as COSV64066515; called by muse, mutect2, varscan2
- MDN1 | c.16578T>G p.V5526= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV65522974; called by muse, mutect2
- MS4A5 | c.498T>A p.I166= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV55741114; called by muse, mutect2, varscan2
- NEB | c.12285C>T p.N4095= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs368315700; called by muse, mutect2
- NOTCH3 | c.984C>G p.T328= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV54637297; called by muse, mutect2, varscan2
- OBSCN | c.18714G>A p.L6238= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs995169977, COSV52782847; called by muse, mutect2, varscan2
- OR10G8 | c.84C>T p.V28= | Silent (SNP) | VAF 88/251 reads (35%) | catalogued as COSV70908656; called by muse, varscan2
- OR4C13 | c.45T>C p.L15= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV73648785; called by muse, mutect2
- OR4S2 | c.273C>G p.S91= | Silent (SNP) | VAF 53/285 reads (19%) | catalogued as COSV56746144, COSV56747064, COSV56747184; called by muse, mutect2, varscan2
- OR5D14 | c.735C>A p.S245= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV100162255; called by muse, mutect2, varscan2
- OR6F1 | c.582A>C p.A194= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as COSV57468127; called by muse, mutect2, varscan2
- OR7G3 | c.120G>T p.L40= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV59640467; called by muse, mutect2, varscan2
- PCDHB7 | c.1402C>T p.L468= | Silent (SNP) | VAF 84/160 reads (53%) | catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCSK7 | c.357T>A p.A119= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV56119274; called by muse, mutect2
- PEG3 | c.4578T>G p.T1526= | Silent (SNP) | VAF 60/182 reads (33%) | catalogued as COSV55626937, COSV55641370; called by muse, mutect2, varscan2
- PLAG1 | c.651T>C p.Y217= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs751455867, COSV57611980; called by muse, mutect2
- PLEC | c.11643G>T p.V3881= (on ENST00000322810 / NM_201380.4; = p.V3771= on NM_000445.5) | Silent (SNP) | VAF 33/45 reads (73%) | catalogued as COSV59645953; called by muse, mutect2, varscan2
- PRKAR1B | c.1005G>T p.R335= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1212699117, COSV64318870; called by muse, mutect2, varscan2
- PRODH2 | c.918C>A p.A306= (on ENST00000301175; = p.A230= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56560205; called by muse, mutect2
- PROKR2 | c.696C>T p.F232= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs758720468, COSV54085808; called by muse, mutect2, varscan2
- RPGRIP1L | c.3492C>A p.T1164= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV50908171; called by muse, mutect2, varscan2
- RTN2 | c.318C>A p.G106= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV55594455; called by muse, mutect2, varscan2
- RTTN | c.3214C>T p.L1072= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV55346277; called by muse, mutect2, varscan2
- RXRB | c.747G>A p.V249= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV63399767; called by muse, mutect2, varscan2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2
- SGCD | c.252C>T p.F84= (on ENST00000435422 / NM_001128209.2; = p.F85= on NM_000337.5) | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs529830918, COSV61909934; called by muse, mutect2, varscan2
- SLC22A8 | c.1537C>A p.R513= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs780060603, COSV60323958, COSV60325475; called by muse, mutect2, varscan2
- SLC24A3 | c.123G>T p.S41= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs750675336, COSV60121549; called by muse, mutect2, varscan2
- SPATA18 | c.1051A>C p.R351= | Silent (SNP) | VAF 45/77 reads (58%) | catalogued as COSV54645659; called by muse, mutect2, varscan2
- SPEF2 | c.4083A>T p.I1361= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV57429680; called by muse, mutect2, varscan2
- ST6GAL1 | c.375C>G p.S125= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV51470725; called by muse, mutect2
- ST8SIA6 | c.1194C>A p.A398= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs1482369166, COSV66469043; called by muse, mutect2, varscan2
- STON2 | c.1140A>G p.V380= (on ENST00000649389 / NM_001366849.2; = p.V323= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV50846058; called by muse, mutect2, varscan2
- STRIP2 | c.1389G>T p.V463= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV50804920; called by muse, mutect2
- SYCE1 | c.846G>C p.L282= (on ENST00000343131 / NM_001143764.3; = p.L246= on NM_130784.3) | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV58217659; called by muse, mutect2
- TIMM44 | c.693G>A p.L231= | Silent (SNP) | VAF 43/244 reads (18%) | catalogued as COSV54492326; called by muse, mutect2, varscan2
- TMEM132D | c.538C>A p.R180= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV70607867, COSV70623172; called by muse, mutect2, varscan2
- UNC5A | c.2403C>A p.A801= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV52841003; called by muse, mutect2, varscan2
- USP21 | c.1539C>T p.S513= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as rs1368794125, COSV57088470; called by muse, mutect2
- VPS41 | c.1935G>A p.E645= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as COSV59649515; called by muse, mutect2, varscan2
- VPS41 | c.1320A>G p.G440= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV59649522; called by muse, mutect2
- WDR26 | c.1305C>T p.D435= (on ENST00000414423 / NM_001379403.1; = p.D335= on NM_025160.7) | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as rs140689711; called by muse, mutect2, varscan2
- ZFP30 | c.174A>T p.L58= | Silent (SNP) | VAF 89/264 reads (34%) | catalogued as COSV63622704; called by muse, mutect2, varscan2
- ZNF135 | c.1143C>T p.P381= (on ENST00000313434 / NM_001289401.2; = p.P393= on NM_003436.4) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV57882897; called by muse, mutect2, varscan2
- ZNF638 | c.1413G>A p.S471= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs764599687, COSV52488776; called by muse, mutect2
- ZNF708 | c.1197A>G p.K399= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV63607607; called by muse, mutect2, varscan2
- ZPLD1 | c.531G>T p.V177= (on ENST00000466937 / NM_001329788.1; = p.V193= on NM_175056.2) | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV60354089; called by muse, mutect2, varscan2
- ZYX | c.1299C>T p.C433= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs374951395; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824072 C>G | 5'Flank (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34539G>A | Intron (SNP) | VAF 32/116 reads (28%) | catalogued as rs768327909, COSV99399441; called by muse, mutect2, varscan2
- MACROD2 | c.1315+3359T>C | Intron (SNP) | VAF 6/112 reads (5%) | catalogued as COSV53996011; called by muse, mutect2
- MSH4 | c.-1G>T | 5'UTR (SNP) | VAF 47/77 reads (61%) | catalogued as COSV99592096; called by muse, mutect2, varscan2
- OR52A4P | n.917C>A | RNA (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
